Somatic mutation profile of tumor specimen BA2694D (aliquot aq-BA2694D) from BEATAML1.0 case 2552, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.5 years (27,940 days).
Specimen BA2694D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ede8b0c-f785-41c7-8da5-a6835bebcd88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2367D (Solid Tissue Normal), aliquot aq-BA2367D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e1f5c70-9be8-4e1a-8b45-94cddbe024ce

The open-access MAF lists 80 somatic variants for this specimen: 58 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Intron 6, Splice Region 1, RNA 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1750G>C p.G584R | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs121913626, CM032603, CM920491, COSV62520888; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.609C>G p.D203E | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52168440; called by muse, mutect2, varscan2
- BMP2K | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs930544200, COSV58592918; called by muse, mutect2, varscan2
- CCIN | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV58725732; called by muse, mutect2
- COBL | c.1706C>G p.S569W | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs375644713; called by muse, mutect2, varscan2
- DDN | c.580G>C p.G194R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.927); catalogued as rs1017816540; called by muse, mutect2
- EPHA10 | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60403938; called by muse, mutect2, varscan2
- FBN3 | c.6688G>A p.G2230S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142411053; called by muse, varscan2
- FBN3 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs781766536; called by muse, varscan2
- KLHL29 | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV72085945; called by muse, mutect2, varscan2
- LITAF | c.385G>C p.A129P | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as CM146134; called by muse, mutect2, varscan2
- MACF1 | c.2476G>C p.D826H | Missense Mutation (SNP) | VAF 28/100 reads (28%) | catalogued as COSV58403804; called by muse, mutect2, varscan2
- MBNL1 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56826346, COSV56835920; called by muse, mutect2
- MTSS2 | c.562C>G p.R188G | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV58697567; called by muse, mutect2, varscan2
- NR2F6 | c.877G>C p.G293R | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV52244334; called by muse, mutect2
- OR6B3 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs774035456; called by muse, varscan2
- RNF168 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs746331793; called by muse, mutect2, varscan2
- RYR1 | c.3780C>G p.D1260E | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs746617954, COSV62089575; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA17 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV65121989; called by muse, mutect2, varscan2
- TOX3 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as rs201164572; called by muse, mutect2, varscan2
- VIPR2 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471198281; called by muse, varscan2
- ADAMTS20 | c.1161C>G p.C387W | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADH1A | c.30C>G p.C10W | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CATSPERE | c.2545C>G p.P849A | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC58 | c.324+5G>C | Splice Region (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- CCL16 | c.89G>C p.W30S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL19A1 | c.134C>G p.T45R | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBL | c.621G>C p.R207S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHDC1 | c.1844C>G p.P615R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- GASK1A | c.1190C>G p.A397G | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- GULP1 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2
- HTR3D | c.1058C>G p.T353S (on ENST00000382489 / NM_001163646.2; = p.T178S on NM_182537.3) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- IBTK | c.1569C>G p.N523K | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INPP4A | c.2730G>C p.Q910H (on ENST00000074304 / NM_001134224.1; = p.Q871H on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIAA1549 | c.3019G>C p.V1007L | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- LRIT2 | c.471C>G p.D157E | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP1B | c.7967C>G p.T2656S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBOAT4 | c.392C>G p.T131R | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MNX1 | c.1039C>G p.R347G | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, mutect2
- MUC12 | c.9173G>C p.S3058T (on ENST00000379442; = p.S2915T on NM_001164462.1) | Missense Mutation (SNP) | VAF 48/795 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.683); called by muse, mutect2
- NF1 | c.6370G>C p.G2124R (on ENST00000358273 / NM_001042492.3; = p.G2103R on NM_000267.3) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PODXL | c.1535C>G p.T512R (on ENST00000378555 / NM_001018111.3; = p.T480R on NM_005397.4) | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R11 | c.249G>C p.E83D | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PPP1R26 | c.1908C>G p.D636E | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.101); called by muse, varscan2
- RNF26 | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RNF32 | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- RPGRIP1 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RRBP1 | c.2965C>G p.L989V (on ENST00000377813 / NM_001365613.2; = p.L556V on NM_004587.3) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- RUNX1 | c.1184_1197del p.E395Afs*173 (on ENST00000344691 / NM_001001890.3; = p.E422Afs*173 on NM_001754.5) | Frame Shift Del (DEL) | VAF 26/41 reads (63%) | called by mutect2, pindel, varscan2
- SOGA1 | c.2071G>C p.D691H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- SUSD5 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SYDE1 | c.2121C>G p.F707L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.074); called by muse, varscan2
- TFIP11 | c.1730C>G p.A577G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS6 | c.618G>C p.L206F | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- TNS1 | c.3112C>G p.R1038G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- TRDN | c.2130C>G p.D710E | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); called by muse, varscan2
- TRHDE | c.2175C>G p.F725L | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ZFHX4 | c.4157C>A p.P1386Q | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC011005.1 | c.1002C>T p.N334= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs1453528319; called by muse, mutect2, varscan2
- ASPG | c.381C>G p.S127= | Silent (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- BACE1 | c.1098C>T p.Y366= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV56121290; called by muse, mutect2, varscan2
- BRICD5 | c.609G>C p.L203= | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- CNDP1 | c.438G>A p.T146= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs371313911, COSV62594396; called by muse, mutect2, varscan2
- FSCN2 | c.1242G>C p.L414= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- GANAB | c.936C>G p.G312= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- GEMIN4 | c.141G>C p.V47= | Silent (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- HEYL | c.414C>G p.P138= | Silent (SNP) | VAF 17/70 reads (24%) | called by muse, mutect2, varscan2
- KRT14 | c.375C>G p.R125= | Silent (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- NOTCH1 | c.249A>G p.A83= | Silent (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- PARD6G | c.654G>A p.E218= | Silent (SNP) | VAF 65/202 reads (32%) | catalogued as rs756436012; called by muse, mutect2, varscan2
- SLC45A1 | c.1509G>A p.A503= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs575632472, COSV57094308; called by muse, mutect2
- ZNF862 | c.426G>C p.S142= | Silent (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- CYB5B | c.333+52G>C | Intron (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- DCHS2 | n.7374G>C | RNA (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- EDC4 | c.3629+28G>C | Intron (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- FBLN5 | c.*6G>C | 3'UTR (SNP) | VAF 39/158 reads (25%) | called by muse, mutect2, varscan2
- LMO3 | c.206+6437C>G | Intron (SNP) | VAF 7/124 reads (6%) | called by muse, mutect2
- MASP1 | c.1303+5779G>C | Intron (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- PDLIM3 | c.94-518G>C | Intron (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- YKT6 | c.460-189G>C | Intron (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
